Somatic mutation profile of tumor specimen TCGA-Y8-A896-01A (aliquot TCGA-Y8-A896-01A-11D-A35Z-10) from TCGA case TCGA-Y8-A896, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 62.3 years (22,750 days).
Specimen TCGA-Y8-A896-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79b6b24f-7e72-414e-8f94-e7e0f8e9b72a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Y8-A896-10A (Blood Derived Normal), aliquot TCGA-Y8-A896-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9342ed2c-1e45-4181-ab25-d95346844f72

The open-access MAF lists 113 somatic variants for this specimen: 87 protein-altering or splice-affecting, 21 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 21, Frame Shift Del 7, Splice Site 4, 5'UTR 3, Frame Shift Ins 3, Nonsense Mutation 3, In Frame Del 2, 3'Flank 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD11 | c.224T>A p.L75H | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99766615; called by muse, mutect2, varscan2
- ANKAR | c.1108T>C p.F370L | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99853762; called by muse, mutect2, varscan2
- ANKK1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs533347208, COSV100392619; called by muse, mutect2, varscan2
- ATP12A | c.2777G>C p.R926T | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99516758; called by muse, mutect2, varscan2
- ATXN7L2 | c.986G>A p.S329N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1426602876, COSV100881283; called by muse, mutect2, varscan2
- AXDND1 | c.2568_2570del p.E856del | In Frame Del (DEL) | VAF 166/632 reads (26%) | catalogued as rs755552478; called by pindel, varscan2
- BMS1 | c.3637G>C p.A1213P | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100996393; called by muse, mutect2, varscan2
- CDC25A | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56770196; called by muse, mutect2, varscan2
- CDH18 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs376117433; called by muse, mutect2, varscan2
- CER1 | c.406C>G p.H136D | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV101097714; called by muse, mutect2, varscan2
- CHRND | c.820+2T>C p.X274_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as CD012239, COSV99285436; called by muse, mutect2, varscan2
- CLPX | c.1112A>G p.Q371R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV100269245; called by muse, mutect2, varscan2
- CLSTN3 | c.1372A>C p.T458P | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.817); catalogued as COSV99866344; called by muse, mutect2, varscan2
- CLUH | c.3341T>G p.L1114R (on ENST00000435359; = p.L1153R on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101425590; called by muse, mutect2, varscan2
- CMYA5 | c.6721G>A p.V2241I | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV101483696; called by muse, mutect2, varscan2
- COX7C | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99915142; called by muse, mutect2, varscan2
- F5 | c.668G>T p.S223I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100888813, COSV63123450; called by muse, mutect2, varscan2
- FAM91A1 | c.1262T>A p.L421H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100593404; called by muse, mutect2, varscan2
- FASTKD2 | c.549C>A p.N183K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV99378741; called by muse, mutect2, varscan2
- FYCO1 | c.4245G>C p.Q1415H | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV99945018; called by muse, mutect2, varscan2
- GAL3ST3 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as rs1329308975, COSV61749061; called by muse, mutect2, varscan2
- GLRA1 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 35/117 reads (30%) | catalogued as rs941253191, COSV99199378; called by muse, mutect2, varscan2
- GNAI1 | c.623G>C p.R208P | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100650337, COSV63522913; called by muse, mutect2, varscan2
- GRIA1 | c.1417G>T p.A473S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99597513; called by muse, mutect2, varscan2
- GRM4 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.765); catalogued as COSV100945579, COSV65217338; called by muse, mutect2, varscan2
- HGF | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 163/364 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs763072412, COSV55956695, COSV99735158; called by muse, mutect2, varscan2
- HMCN1 | c.5902A>G p.T1968A | Missense Mutation (SNP) | VAF 67/271 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99622295; called by muse, mutect2, varscan2
- HOXA1 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 23/115 reads (20%) | catalogued as COSV99760919; called by muse, mutect2, varscan2
- IGF2BP2 | c.1604T>C p.L535P | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100648804; called by muse, mutect2, varscan2
- IMPDH2 | c.535A>G p.M179V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100454879; called by muse, mutect2, varscan2
- IQCF2 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV100290979; called by muse, mutect2
- ITGB1BP1 | c.390G>T p.L130F | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99431695; called by muse, mutect2, varscan2
- JMJD1C | c.5027G>T p.R1676M | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100550047; called by muse, mutect2, varscan2
- KCTD1 | c.227T>C p.F76S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517382; called by muse, mutect2, varscan2
- LAMC1 | c.722A>G p.Q241R | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99278674; called by muse, mutect2, varscan2
- MBOAT7 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV99824510; called by muse, varscan2
- MFHAS1 | c.3001G>C p.E1001Q | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV52280054; called by muse, mutect2, varscan2
- MYT1 | c.2222G>A p.R741K | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.086); catalogued as rs1286932596, COSV100113739; called by muse, mutect2, varscan2
- NAA30 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100035719; called by muse, mutect2, varscan2
- NID2 | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99355748, COSV99356199; called by muse, mutect2, varscan2
- NUP210L | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV99666900; called by muse, mutect2, varscan2
- OGT | c.190A>C p.I64L | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV101035110; called by muse, mutect2, varscan2
- PER1 | c.1822C>A p.L608I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV100424157; called by muse, mutect2, varscan2
- PGBD5 | c.623A>C p.K208T (on ENST00000525115; = p.K277T on NM_001258311.2) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100358282, COSV58414042; called by muse, mutect2, varscan2
- PLXNB1 | c.352G>T p.V118F | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs368626600, COSV56486561; called by muse, mutect2, varscan2
- POLI | c.1643C>A p.S548Y | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99470736; called by muse, mutect2, varscan2
- POP7 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100292142; called by muse, mutect2, varscan2
- PSG1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs368581835; called by muse, mutect2, varscan2
- PSMD7 | c.324C>G p.I108M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99542513; called by muse, mutect2, varscan2
- PUS7L | c.1033T>C p.Y345H | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61262410, COSV61262621; called by muse, mutect2, varscan2
- RGL1 | c.2118A>G p.K706= (on ENST00000360851 / NM_001297672.2; = p.K741= on NM_015149.5 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100486041; called by muse, mutect2, varscan2
- RNF123 | c.292C>A p.H98N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100570083; called by muse, mutect2, varscan2
- RNF208 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.548); catalogued as COSV100763092, COSV100763112; called by muse, mutect2, varscan2
- RORA | c.842C>T p.S281F (on ENST00000335670 / NM_134261.3; = p.S306F on NM_002943.3) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as COSV99832019; called by muse, mutect2, varscan2
- RSPH10B2 | c.180C>A p.D60E | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1421306631, COSV51870923; called by muse, mutect2, varscan2
- SEMA4F | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); catalogued as rs774544086, COSV100335630; called by muse, mutect2, varscan2
- SGK2 | c.433A>G p.S145G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV100414528; called by muse, mutect2, varscan2
- SGK2 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs559824768, COSV58313047; called by muse, mutect2, varscan2
- SLC20A1 | c.481T>G p.S161A | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs774593041, COSV99733804; called by muse, mutect2, varscan2
- SLC2A4RG | c.943A>T p.S315C | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV99828599; called by muse, mutect2, varscan2
- SLC35G1 | c.410G>A p.G137E (on ENST00000427197 / NM_001134658.3; = p.G136E on NM_153226.4) | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779017955, COSV101003996; called by muse, mutect2, varscan2
- SMARCC1 | c.2323G>A p.G775R | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV99592071; called by muse, mutect2, varscan2
- SPEN | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1416835470, COSV101004933; called by muse, mutect2, varscan2
- STKLD1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.691); catalogued as COSV100911841; called by muse, mutect2, varscan2
- SYNE2 | c.2018T>C p.L673P | Missense Mutation (SNP) | VAF 85/337 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100646357; called by muse, mutect2, varscan2
- TAX1BP1 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 71/305 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.497); catalogued as COSV99603958; called by muse, mutect2, varscan2
- TERF1 | c.92C>G p.T31R | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.074); catalogued as COSV99400774; called by muse, mutect2, varscan2
- THOC1 | c.1931A>G p.D644G | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as COSV99863166; called by muse, mutect2, varscan2
- TSC22D1 | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs370025988; called by muse, mutect2, varscan2
- TTC16 | c.426+1G>A p.X142_splice | Splice Site (SNP) | VAF 21/46 reads (46%) | catalogued as COSV100076636; called by muse, mutect2, varscan2
- UMODL1 | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100210424; called by muse, mutect2, varscan2
- VASN | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs192543506; called by muse, mutect2, varscan2
- ZFAT | c.2831A>G p.K944R | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs747380490, COSV100914088; called by muse, mutect2, varscan2
- ZNF839 | c.1160A>C p.K387T (on ENST00000558850 / NM_001267827.1; = p.K503T on NM_018335.5) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99215951; called by muse, mutect2, varscan2
- ABCC5 | c.807del p.E270Rfs*37 | Frame Shift Del (DEL) | VAF 27/149 reads (18%) | called by mutect2, pindel, varscan2
- ATP2A3 | c.1481del p.M494Sfs*21 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- CAMK1D | c.1064del p.S355Ifs*23 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- DNMT3A | c.1272_1279+6del p.X424_splice | Splice Site (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- LBX2 | c.452_455dup p.S153Rfs*33 (on ENST00000377566 / NM_001282430.2; = p.S149Rfs*33 on NM_001009812.2) | Frame Shift Ins (INS) | VAF 24/99 reads (24%) | called by mutect2, pindel, varscan2
- NCF4 | c.470+2_470+3del p.X157_splice | Splice Site (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- NF2 | c.828_829dup p.D277Gfs*20 | Frame Shift Ins (INS) | VAF 31/85 reads (36%) | called by mutect2, pindel, varscan2
- PCK1 | c.42dup p.V15Sfs*20 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- SALL1 | c.3127_3131del p.N1043Efs*18 | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | called by mutect2, pindel, varscan2
- UBA5 | c.1201del p.M401* | Frame Shift Del (DEL) | VAF 28/131 reads (21%) | called by mutect2, pindel, varscan2
- UBE4A | c.1724_1728del p.M575Rfs*27 (on ENST00000252108 / NM_001204077.2; = p.M582Rfs*27 on NM_004788.4) | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | called by mutect2, pindel, varscan2
- ZNF24 | c.266_274del p.E89_L92delinsV | In Frame Del (DEL) | VAF 48/160 reads (30%) | called by mutect2, pindel, varscan2
- ZNF676 | c.1117_1129del p.E373Lfs*153 (on ENST00000650058; = p.E341Lfs*153 on NM_001001411.3) | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by pindel, varscan2
- ADCY3 | c.1500G>A p.K500= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV99567471; called by muse, mutect2, varscan2
- ADCY8 | c.601T>C p.L201= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs1156299387, COSV99650092; called by muse, mutect2, varscan2
- AHDC1 | c.4506C>T p.A1502= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV99898737; called by muse, mutect2, varscan2
- ASAP2 | c.1308C>T p.C436= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV99855575; called by muse, mutect2, varscan2
- ATG9A | c.270C>T p.D90= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as rs770730811, COSV100036633; called by muse, mutect2, varscan2
- CDC16 | c.579G>T p.L193= | Silent (SNP) | VAF 128/440 reads (29%) | catalogued as COSV99372625; called by muse, mutect2, varscan2
- COL7A1 | c.4764G>A p.K1588= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs774196875, COSV100094549, COSV60397499; called by muse, mutect2, varscan2
- DENND4C | c.5850G>A p.R1950= (on ENST00000434457 / NM_001330640.2; = p.R1901= on NM_017925.7) | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100194370; called by muse, mutect2, varscan2
- ELL | c.1830C>T p.A610= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs777550277, COSV99442603; called by muse, mutect2, varscan2
- EPB41L3 | c.2619G>A p.S873= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs764952165, COSV59449297, COSV59453657; called by muse, mutect2, varscan2
- FXR1 | c.1476T>C p.D492= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as COSV59761629; called by muse, mutect2, varscan2
- IFIT1 | c.855C>T p.V285= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs373034374, COSV100878647; called by muse, mutect2, varscan2
- INHBB | c.804C>G p.G268= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as COSV99735530; called by muse, mutect2, varscan2
- OR2AT4 | c.495A>G p.V165= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100532238; called by muse, mutect2, varscan2
- PCDHB1 | c.534C>T p.F178= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV60633758; called by muse, mutect2, varscan2
- PTPN21 | c.3378C>G p.A1126= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV100161328; called by muse, mutect2, varscan2
- SORBS1 | c.1527A>G p.S509= (on ENST00000361941 / NM_001034954.2; = p.S299= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV99527177; called by muse, mutect2, varscan2
- TMEM26 | c.513A>G p.R171= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV99515376; called by muse, mutect2, varscan2
- TRRAP | c.8565C>T p.C2855= (on ENST00000359863 / NM_001244580.1; = p.C2837= on NM_003496.3) | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs777625422, COSV62840828; called by muse, mutect2, varscan2
- TTC32 | c.109C>A p.R37= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100367747; called by muse, mutect2, varscan2
- TTC6 | c.132T>A p.I44= (on ENST00000267368; = p.I1313= on NM_001310135.3) | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV99941401; called by muse, mutect2
- AL136295.1 | c.-13A>T | 5'UTR (SNP) | VAF 21/79 reads (27%) | catalogued as COSV99164571; called by muse, mutect2, varscan2
- BCDIN3D | c.-1A>C | 5'UTR (SNP) | VAF 26/79 reads (33%) | catalogued as rs759402863, COSV100445418; called by muse, mutect2, varscan2
- DCAF6 | c.-2C>T | 5'UTR (SNP) | VAF 66/207 reads (32%) | catalogued as COSV99607428; called by muse, mutect2, varscan2
- ESPN | chr1:6457248 A>G | 3'Flank (SNP) | VAF 46/168 reads (27%) | catalogued as COSV100696861; called by muse, mutect2, varscan2
- PDE4A | c.784-1550_784-1548delinsAA | Intron (DEL) | VAF 14/38 reads (37%) | called by pindel, varscan2*
